Somatic mutation profile of cancer-model specimen HCM-BROD-0044-C15-85B (3D Organoid, passage 7; aliquot HCM-BROD-0044-C15-85B-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0044-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 36.1 years (13,168 days).
Specimen HCM-BROD-0044-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3af19894-91b9-4c81-a7b9-c243c4d13446.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0044-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0044-C15-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ea2990-b909-4d0c-a92d-be11a2a319e7

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 1, 5'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 209/209 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABR | c.1613C>A p.A538D (on ENST00000302538 / NM_021962.5; = p.A501D on NM_001092.5) | Missense Mutation (SNP) | VAF 271/271 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52144828; called by muse, mutect2, varscan2
- ADRB1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 241/470 reads (51%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.877); catalogued as rs1365098433; called by muse, mutect2, varscan2
- AK9 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 144/223 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100393629; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 142/142 reads (100%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- ARMCX2 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); catalogued as COSV57530257; called by muse, mutect2
- CACNG5 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1230744913, COSV50054808, COSV99400424; called by muse, mutect2, varscan2
- CFAP44 | c.1858del p.V620Cfs*4 | Frame Shift Del (DEL) | VAF 136/364 reads (37%) | catalogued as COSV99869627; called by mutect2, pindel, varscan2
- CHD8 | c.4484G>A p.R1495H (on ENST00000646647 / NM_001170629.2; = p.R1216H on NM_020920.4) | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs376523446, COSV100783794; called by muse, mutect2, varscan2
- EPHA3 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 70/294 reads (24%) | catalogued as COSV60696954, COSV60707019; called by muse, mutect2, varscan2
- EVX2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 144/492 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100420669; called by muse, mutect2, varscan2
- FEZF2 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs760244679; called by muse, mutect2
- LRRC45 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs753160647, COSV60711078; called by muse, mutect2, varscan2
- PCDHB3 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 490/491 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV50567411; called by muse, mutect2, varscan2
- PHF12 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 305/452 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99255765; called by muse, mutect2, varscan2
- SEMA5A | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 297/516 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1407782671, COSV66789974; called by muse, mutect2, varscan2
- SPATC1L | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 232/610 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs975146735; called by muse, mutect2, varscan2
- SRBD1 | c.264T>C p.N88= | Splice Region (SNP) | VAF 11/229 reads (5%) | catalogued as rs1341186275; called by muse, mutect2
- SRMS | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs780151368, COSV99420841; called by muse, mutect2
- SUMO3 | c.151-36_156del p.X51_splice | Splice Site (DEL) | VAF 60/176 reads (34%) | catalogued as rs1448853522; called by muse*, mutect2
- TPD52L2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 245/379 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1028523536; called by muse, mutect2, varscan2
- ZSWIM2 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs1444421885; called by muse, mutect2, varscan2
- ATXN7 | c.2071_2074del p.N691Vfs*59 | Frame Shift Del (DEL) | VAF 302/310 reads (97%) | called by mutect2, pindel, varscan2
- BEND2 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 152/346 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- BRD2 | c.1935_1951del p.D645Efs*28 | Frame Shift Del (DEL) | VAF 283/662 reads (43%) | called by mutect2, pindel, varscan2
- C17orf98 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 152/1476 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- CDS2 | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- CREB3L2 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 124/536 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DAGLA | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 174/778 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DLGAP2 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLL1 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 48/535 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GCLM | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRIN2B | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 143/453 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KCNJ6 | c.28A>C p.N10H | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- LMF1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 199/545 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PAQR7 | c.574A>T p.N192Y | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2
- RHOC | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 155/421 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A43 | c.227G>C p.C76S | Missense Mutation (SNP) | VAF 14/511 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- SLITRK2 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 367/367 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPIDR | c.324G>C p.L108F | Missense Mutation (SNP) | VAF 198/443 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- UGT2A3 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- VSTM2B | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF100 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF418 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 149/450 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZP3 | c.1024C>A p.Q342K (on ENST00000394857 / NM_001110354.2; = p.Q291K on NM_007155.6) | Missense Mutation (SNP) | VAF 150/1270 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ANK3 | c.6153C>T p.Y2051= | Silent (SNP) | VAF 26/540 reads (5%) | called by muse, mutect2
- CEP192 | c.6631T>C p.L2211= | Silent (SNP) | VAF 68/263 reads (26%) | called by muse, mutect2, varscan2
- CER1 | c.597G>C p.A199= | Silent (SNP) | VAF 30/306 reads (10%) | catalogued as rs527955982, COSV101097934; called by muse, mutect2
- CRISP2 | c.234C>T p.C78= | Silent (SNP) | VAF 14/452 reads (3%) | called by muse, mutect2
- EFCAB6 | c.3798C>T p.D1266= | Silent (SNP) | VAF 260/260 reads (100%) | catalogued as rs144783076; called by muse, mutect2, varscan2
- LGR5 | c.720T>C p.D240= | Silent (SNP) | VAF 146/205 reads (71%) | called by muse, mutect2, varscan2
- MAPK1IP1L | c.372A>G p.P124= | Silent (SNP) | VAF 156/453 reads (34%) | called by muse, mutect2, varscan2
- MKRN3 | c.546C>T p.A182= | Silent (SNP) | VAF 252/425 reads (59%) | catalogued as rs200863828, COSV100091116; called by muse, mutect2, varscan2
- MUC16 | c.28764C>A p.T9588= | Silent (SNP) | VAF 32/354 reads (9%) | catalogued as rs1175898517; called by muse, mutect2
- MUC16 | c.28323A>C p.S9441= | Silent (SNP) | VAF 10/263 reads (4%) | called by muse, mutect2
- PM20D1 | c.12G>A p.R4= | Silent (SNP) | VAF 96/291 reads (33%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1122C>T p.I374= | Silent (SNP) | VAF 497/840 reads (59%) | catalogued as rs761278697; called by muse, mutect2, varscan2
- SPEN | c.3279T>C p.G1093= | Silent (SNP) | VAF 124/388 reads (32%) | called by muse, mutect2, varscan2
- SPTB | c.2547C>T p.D849= | Silent (SNP) | VAF 347/522 reads (66%) | called by muse, mutect2, varscan2
- TENM1 | c.2493T>C p.S831= | Silent (SNP) | VAF 32/292 reads (11%) | called by muse, mutect2, varscan2
- TYRO3 | c.135C>T p.L45= | Silent (SNP) | VAF 64/522 reads (12%) | catalogued as rs781119325; called by muse, mutect2
- COPS9 | chr2:240136346 A>G | 5'Flank (SNP) | VAF 40/418 reads (10%) | called by muse, mutect2
- GPM6A | c.37+24841T>C | Intron (SNP) | VAF 191/191 reads (100%) | called by muse, mutect2, varscan2
